Surgical pathology report (de-identified scan), TCGA case TCGA-34-2609, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2609-01A (Primary Tumor).

[page 1 of 3]
CLINICAL HISTORY

The patient is an [REDACTED] year old male with history of lung mass.

PRE-OP DIAGNOSIS: Lung mass.

POST-OP DIAGNOSIS: Not given.

PROCEDURE: Not given.

ES/js

ADDENDUM

Fluorescence in situ hybridization studies performed on the squamous cell carcinoma show a ratio of EGF-R gene to the centromere of chromosome 7 of 1.12 indicating a lack of amplification in the targeted area.

The Department of Pathology is in receipt of Oncotech report [REDACTED]

s

FINAL DIAGNOSIS**Summary Statement**

The right lower lobectomy demonstrates a 5.0 cm, moderately differentiated squamous cell carcinoma with metastasis to one of twelve N1 lymph nodes and associated with angiolymphatic invasion. All margins free. Pathologic stage T2 N1 MX.

PART 1: LUNG, RIGHT LOWER LOBE, BRONCHOSCOPIC BIOPSY

FRAGMENTS OF BRONCHIAL MUCOSA WITH NO SIGNIFICANT ABNORMALITY. GROCOTT STAINS ARE NEGATIVE.

PART 2: PLEURA, RIGHT, PLEURECTOMY

HYALINE PLEURAL PLAQUE ASSOCIATED WITH CHRONIC PLEURITIS.

PART 3: LYMPH NODE, "LEVEL 11", BIOPSY

TWO FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 4: LYMPH NODE, "LEVEL 11 SUMP", BIOPSY

TWO FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 5: LYMPH NODE, "LEVEL 12-R", BIOPSY

THREE FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 6: LYMPH NODE, "LEVEL 4", BIOPSY

FOUR FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 7: LUNG, RIGHT LOWER LOBE, LOBECTOMY

A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA ASSOCIATED WITH ANGIOLYMPHATIC INVASION. DIAMETER 5.0 CM. NO EVIDENCE OF VISCERAL PLEURAL INVASION. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T2 N1 MX.

B. ONE OF FIVE HILAR LYMPH NODES WITH METASTATIC SQUAMOUS CELL CARCINOMA.

C. MILD EMPHYSEMATOUS CHANGE WITH RESPIRATORY BRONCHIOLITIS AND FOCAL SUBPLEURAL SCARRING WITH OBSTRUCTIVE CHANGE.

PART 8: LYMPH NODE, LEVEL 7, BIOPSY

THREE FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

[page 2 of 3]
PART 9: LYMPH NODE, LEVEL 10, BIOPSY

SOLITARY FRAGMENT OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

COMMENT

{Not Entered}

GROSS DESCRIPTION

The specimen is received in nine parts.

Part 1 is received fresh, properly identified with the patient's ID, initials and labeled as "right lower lobe". It consists of a single piece of unoriented white-tan soft tissue, measuring 0.6 cm in greatest dimension. The specimen is entirely submitted in cassette 1A.

Part 2 is received fresh, properly identified with the patient's ID, initials and labeled as "right pleura". It consists of a piece of unoriented pink-tan membranous tissue (4.0 x 2.2 x 0.6 cm), in which two relatively discrete areas of white-tan hard thickening is present. Representative sections mainly from thickened areas are submitted in cassettes 2A-2B.

Part 3 is received fresh, properly identified with the patient's ID, initials and labeled as "level 11". It consists of two pieces of dark red and black soft tissue, measuring 1.1 cm and 0.6 cm in greatest dimension for each. The tissue is entirely submitted intact in cassette labeled 3A.

Part 4 is received fresh, properly identified with the patient's ID, initials and labeled as "level 11, sump". It consists of two pieces of white-tan flat soft tissue, measuring 2.5 and 1.3 cm in greatest dimensions for each with focal anthracotic pigmentation. The specimen is entirely submitted intact in cassettes labeled 4A and 4B.

Part 5 is received fresh, properly identified with the patient's ID, initials and labeled as "level 12-R". It consists of three pieces of white-tan and focally black soft tissue, measuring up to 0.7 cm in greatest dimension. The specimen is entirely submitted intact in cassette labeled 5A.

Part 6 is received fresh, properly identified with the patient's ID, initials and labeled as "level 4". It consists of four pieces of flat yellow adipose tissue, measuring 1.2 to 1.8 cm, containing small areas of anthracotic, pigmented deposition. The specimen is entirely submitted intact in cassettes 6A and 6B.

Part 7 is received in formalin, properly identified with the patient's ID, initials and labeled as "right lower lobe". It is a previously opened lobectomy specimen of the lung (120 grams, 15.0 x 12.0 x 2.0 cm) with a single staple line measuring 5.5 cm in length in its medial aspect. The pleural surface has been inked blue. On sectioning, a 5.0 x 5.0 x 4.8 cm white-tan mass with extensive cavitation is present near the medial/anterior surface of the lobectomy specimen. The tumor is present directly beneath the pleural surface (< 1 mm to the surface), but does not show retraction of the overlying pleura. The tumor is located at least 2.5 cm distal to the bronchial and vascular margins. The remaining portion of the lung parenchyma is dark red spongy and shows no significant abnormality. No satellite nodule is identified in the rest of lung tissue. Representative sections are submitted as follows:

7A part of tumor submitted for frozen section

7B-7C bronchial and vascular margins

7D representative section of staple line

7E-7F tumor and pleura

7G tumor and closest bronchus including three peribronchial lymph nodes.

7H tumor and closest vasculature

7I additional random section of tumor

7J representative lung parenchyma

7K hilar lymph node, 1 lymph node bisected

[page 3 of 3]
Part 8 is received fresh, properly identified with patient's ID, initials [REDACTED] and labeled as "level 7". It consists of three pieces of dark red and partially black soft tissue, measuring 1.8, 1.5 and 1.5 cm in greatest dimension for each. Each piece of tissue is bisected and submitted in cassette labeled 8A-8C.

Part 9 is received fresh, properly identified with patient's ID< initials [REDACTED] and labeled as "level 10". It consists of a single piece of black soft tissue, measuring 0.4 cm in greatest dimension. The specimen is entirely submitted intact in cassette labeled 9A.

MICROSCOPIC DESCRIPTION

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION: Right Lower Lobe

PROCEDURE: Lobectomy

TUMOR SIZE: Maximum dimension: 5.0 cm

Minor dimension: 4.8 cm

GROSS SATELLITES: Number of gross satellite lesions: 0

TUMOR TYPE: Invasive squamous carcinoma

HISTOLOGIC GRADE: G2, Moderately differentiated

MICROSCOPIC SATELLITES: Number of microscopic satellite lesions: 0

EXTRAPULMONARY PARENCHYMAL

EXTENSION/INVASION OF TUMOR: None identified

ANGIOLYMPHATIC INVASION: Yes

TUMOR NECROSIS: < or = to 50%

SURGICAL MARGIN INVOLVEMENT: No

SURGICAL MARGIN SITE: Distance of invasive tumor to closest margin: 25 mm

INFLAMMATORY(DESMOPLASTIC) REACTION: Mild

N1 LYMPH NODES: Number of N1 lymph nodes positive:: 1

Number of N1 lymph nodes examined: 12

N2 LYMPH NODES: Number of N2 lymph nodes positive: 0

Number of N2 lymph nodes examined: 8

UNDERLYING DISEASE(S): Emphysema

T STAGE, PATHOLOGIC: pT2

N STAGE, PATHOLOGIC: pN1

M STAGE, PATHOLOGIC: pMX

ANCILLARY STUDIES: Histochemical stains, FISH studies

Comment: PAS stains show a subplasma level distribution characteristic of squamous carcinoma. PAS/D and mucicarmine stains are negative. Elastic tissue stains show vascular invasion, but not visceral pleural invasion.

INTRAOPERATIVE DIAGNOSIS

7AFS: LUNG, RIGHT LOWER LOBE, LOBECTOMY (frozen section)

A. MALIGNANT.

B. SQUAMOUS CELL CARCINOMA.

C. TUMOR SENT TO ONCOTECH, REQUESTED BY [REDACTED] J.

D. TUMOR AND NORMAL TISSUE PROVIDED FOR TUMOR BANK [REDACTED]

Source: NCI Genomic Data Commons file 25ff4d2f-0e52-4027-a3fb-ebf0ed6abc01 (TCGA-34-2609.8101C165-87F1-4EDC-9756-163156377CAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).